Somatic mutation profile of tumor specimen C3N-00177-01 (aliquot CPT0020100009) from CPTAC case C3N-00177, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 52.5 years (19,161 days).
Specimen C3N-00177-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3852bcf3-1696-45cd-8442-327dcd2d3ced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00177-31 (Blood Derived Normal), aliquot CPT0020940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8b6ec05-bae7-4682-8dcd-0c77752e2679

The open-access MAF lists 75 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Splice Site 4, Frame Shift Del 3, Intron 3, Splice Region 2, 5'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX23 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56400975; called by muse, mutect2, varscan2
- EXOC8 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1366563567, COSV50477683; called by muse, mutect2, varscan2
- IGHV4-39 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 84/555 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767602958; called by muse, mutect2, varscan2
- KLRG2 | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV61800292; called by muse, mutect2
- LCE2C | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs777666120, COSV64228433; called by muse, mutect2, varscan2
- MYH3 | c.5789C>T p.S1930F | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV56866687; called by muse, mutect2, varscan2
- NTNG1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773062054, COSV53964857, COSV53968229; called by muse, mutect2
- NTRK1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs540521894, COSV62324041; ClinVar: uncertain significance; called by muse, mutect2
- PASD1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as rs1202935961, COSV100949275, COSV64854159; called by muse, mutect2, varscan2
- PCDHB3 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs371105731; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.013); catalogued as rs138457517; called by muse, mutect2, varscan2
- SEC31A | c.2032A>T p.N678Y (on ENST00000355196 / NM_001318120.1; = p.N639Y on NM_016211.4) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV52344300; called by muse, mutect2, varscan2
- TMEM151B | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385595151, COSV65255419; called by muse, mutect2, varscan2
- TPD52L1 | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1462468225; called by mutect2, varscan2
- ACAD11 | c.702+1G>T p.X234_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- ADAMTS10 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADD2 | c.1519C>G p.R507G | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AHR | c.2422A>T p.N808Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ANKZF1 | c.2051A>G p.N684S | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP17 | c.630A>T p.K210N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ASTN2 | c.2285G>T p.C762F (on ENST00000313400 / NM_001365069.1; = p.C711F on NM_014010.5) | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BRD7 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPE | c.3556C>T p.Q1186* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- CHD2 | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX36 | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIO1 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- EHBP1L1 | c.2642C>G p.A881G | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- EXD3 | c.2492G>C p.C831S | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FBN1 | c.6076C>A p.L2026M | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXL7 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GALNT1 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HCN1 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMG20A | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KRTAP4-4 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- LRG1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- LRRC47 | c.1256A>C p.E419A | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MORN1 | c.1295del p.L432Qfs*7 | Frame Shift Del (DEL) | VAF 30/237 reads (13%) | called by mutect2, pindel, varscan2
- NBL1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2
- NCKAP5 | c.4709A>T p.K1570M | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- NPM1 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- OR14C36 | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- PCDHAC1 | c.447A>T p.Q149H | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PRMT2 | c.830+1G>T p.X277_splice | Splice Site (SNP) | VAF 14/105 reads (13%) | called by muse, varscan2
- RAD54L | c.1042+7A>C | Splice Region (SNP) | VAF 56/542 reads (10%) | called by mutect2, varscan2
- RIPPLY1 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RNPEP | c.1424C>A p.P475Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- SEC14L1 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SEPTIN7 | c.278_280dup p.X93_splice | Splice Site (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel
- SF3B1 | c.416-10_416-3del | Splice Region (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- SH3TC2 | c.2873-2A>T p.X958_splice | Splice Site (SNP) | VAF 57/509 reads (11%) | called by muse, mutect2, varscan2
- SIK3 | c.3071A>G p.H1024R (on ENST00000445177 / NM_001366686.2; = p.H982R on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SLAMF7 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF7L | c.510del p.Y172Ifs*33 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- UBE4B | c.1752G>T p.E584D (on ENST00000343090 / NM_001105562.3; = p.E455D on NM_006048.5) | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UNC13A | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VHL | c.349del p.W117Gfs*42 | Frame Shift Del (DEL) | VAF 38/250 reads (15%) | called by mutect2, pindel*, varscan2
- ZC3H14 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- B3GALT4 | c.1111C>A p.R371= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1485269770; called by muse, mutect2, varscan2
- COL22A1 | c.3960A>G p.Q1320= | Silent (SNP) | VAF 40/342 reads (12%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.1494A>G p.L498= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs202037583; called by muse, mutect2, varscan2
- EPHA6 | c.1632G>A p.R544= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as COSV67565320, COSV67588697; called by muse, mutect2, varscan2
- FBN1 | c.1392C>T p.R464= | Silent (SNP) | VAF 14/386 reads (4%) | catalogued as COSV57308798; called by muse, mutect2
- H3C1 | c.174C>T p.S58= | Silent (SNP) | VAF 74/510 reads (15%) | catalogued as rs149549865; called by muse, mutect2, varscan2
- HS3ST3A1 | c.927C>T p.F309= | Silent (SNP) | VAF 29/440 reads (7%) | catalogued as rs761345338; called by muse, mutect2
- IL6R | c.666C>T p.I222= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- NTAN1 | c.483G>C p.V161= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- SCYL3 | c.2118C>G p.V706= (on ENST00000367770; = p.V652= on NM_020423.7) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99609228; called by muse, mutect2, varscan2
- SPOCK3 | c.1197T>A p.T399= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- TMEM156 | c.661C>T p.L221= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs1413726476; called by muse, mutect2
- ZBED6 | c.2226G>A p.V742= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- EP400P1 | n.454A>T | RNA (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- MYCBP | c.15+27G>A | Intron (SNP) | VAF 37/151 reads (25%) | catalogued as rs770473342; called by muse, mutect2, varscan2
- PDLIM5 | c.291+53A>G | Intron (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- PGD | c.-52C>T | 5'UTR (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- SPATS2L | c.39+4009A>G | Intron (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2, varscan2
